Somatic mutation profile of tumor specimen TCGA-EB-A24C-01A (aliquot TCGA-EB-A24C-01A-11D-A197-08) from TCGA case TCGA-EB-A24C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.2 years (20,539 days).
Specimen TCGA-EB-A24C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be741107-90f4-4d24-855a-ab5ad59276c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A24C-10A (Blood Derived Normal), aliquot TCGA-EB-A24C-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c75391f1-aeb2-4ed9-91ea-3e9a4cd8e42a

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BACE2 | c.310A>C p.K104Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV57743955; called by muse, mutect2, varscan2
- BEX2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV65501321; called by muse, mutect2, varscan2
- BLK | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1013048438, COSV52056498; called by muse, mutect2, varscan2
- C4BPA | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65537749; called by muse, mutect2, varscan2
- CIITA | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs147670132; called by muse, mutect2, varscan2
- CNTNAP2 | c.978C>G p.S326R | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.381); catalogued as COSV62213361, COSV62262425; called by muse, mutect2, varscan2
- DIO3 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV63774686, COSV63774743; called by muse, mutect2, varscan2
- DPYD | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs201018345, COSV64615647; called by muse, mutect2, varscan2
- ECM2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60740906; called by muse, mutect2, varscan2
- HPS5 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV62540717; called by muse, mutect2
- LYG1 | c.65G>T p.W22L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57916135; called by muse, mutect2, varscan2
- MAMDC4 | c.2454dup p.D819Rfs*33 (on ENST00000445819; = p.D740Rfs*33 on NM_206920.3) | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | catalogued as rs757960326; called by pindel, varscan2
- MOCS1 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51310865; called by muse, mutect2, varscan2
- NCAPD2 | c.393T>G p.F131L | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as COSV59702810; called by muse, mutect2, varscan2
- NMD3 | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63619660; called by mutect2, varscan2
- OCEL1 | c.347T>C p.F116S | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768174600, COSV52245617; called by muse, mutect2, varscan2
- OR4N5 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 117/271 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV61321399; called by muse, mutect2, varscan2
- RBSN | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53795764; called by muse, mutect2, varscan2
- RRBP1 | c.4058T>A p.L1353Q (on ENST00000377813 / NM_001365613.2; = p.L920Q on NM_004587.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55709216; called by muse, mutect2, varscan2
- SLC35B2 | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51492020; called by muse, mutect2, varscan2
- SLITRK3 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1490112678, COSV53847403, COSV53853131; called by muse, mutect2, varscan2
- ZNF219 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53884562; called by muse, mutect2, varscan2
- BPIFA3 | c.228G>T p.L76= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV64926290; called by muse, mutect2, varscan2
- CDR1 | c.210G>A p.S70= | Silent (SNP) | VAF 63/76 reads (83%) | catalogued as rs191541717, COSV100983402, COSV65164850; called by muse, mutect2, varscan2
- CELSR3 | c.5142C>T p.G1714= | Silent (SNP) | VAF 7/37 reads (19%) | called by mutect2, varscan2
- DSCAML1 | c.3705C>T p.D1235= (on ENST00000321322; = p.D1175= on NM_020693.4) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs755969931, COSV58403248; called by mutect2, varscan2
- FARS2 | c.1275G>T p.L425= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as COSV51176092; called by muse, mutect2, varscan2
- MARCHF9 | c.568C>T p.L190= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV56986692; called by muse, mutect2, varscan2
- OR1J4 | c.174C>A p.P58= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV61590338; called by muse, mutect2, varscan2
- PSD2 | c.2046C>T p.V682= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs763351238, COSV51212443; called by muse, mutect2, varscan2
- SAA2 | c.171G>T p.R57= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99879184; called by mutect2, varscan2
- VPS13D | c.12543C>T p.F4181= | Silent (SNP) | VAF 49/59 reads (83%) | catalogued as rs1377569348, COSV50689224; called by muse, mutect2, varscan2
